FM case AD1858 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/ee03fb01-5598-4954-96c3-ff1c3f7b0ff4

Male, 41.9 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the head, face or neck; specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 45% (pathologist estimate recorded by GDC). Sample type: Tumor.
